Somatic mutation profile of tumor specimen TCGA-IB-AAUP-01A (aliquot TCGA-IB-AAUP-01A-11D-A377-08) from TCGA case TCGA-IB-AAUP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.1 years (24,864 days).
Specimen TCGA-IB-AAUP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f196165-6a49-4236-8e74-94ec8adfac55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUP-10A (Blood Derived Normal), aliquot TCGA-IB-AAUP-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fec97cb-977a-4289-b316-2a05c2ed40de

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 21, Silent 11, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 19/610 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54681904, COSV54685721; called by muse, mutect2
- AKAP11 | c.4093G>C p.D1365H | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV99213416; called by muse, mutect2
- CBLN1 | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs1430442103, COSV54654351, COSV99535546; called by muse, mutect2
- CNTN1 | c.2654A>G p.N885S | Missense Mutation (SNP) | VAF 76/1212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768554950, COSV100750880; called by muse, mutect2
- EFTUD2 | c.1622T>C p.V541A | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as rs1338151794, COSV101274510; called by muse, mutect2
- FREM2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 21/452 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as rs544070855, COSV54830770; called by muse, mutect2
- HDGFL2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56684124; called by muse, mutect2
- HERC2 | c.11003G>A p.R3668Q | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99870521; called by muse, mutect2
- HSPA4 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 15/572 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100507526; called by muse, mutect2
- KPNA4 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 24/576 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100514952; called by muse, mutect2
- LCE2B | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 45/1316 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99056556; called by muse, mutect2
- LPA | c.3287+1G>A p.X1096_splice | Splice Site (SNP) | VAF 64/1996 reads (3%) | catalogued as rs767906902, COSV60309190; called by muse, mutect2
- MOK | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99512887; called by muse, mutect2
- NOBOX | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376334807, COSV99779093; called by muse, mutect2
- NRK | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs376128030, COSV54592100; called by muse, mutect2
- OFD1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1376239977, COSV60797202; ClinVar: uncertain significance; called by muse, mutect2
- PAPOLB | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV101271226; called by muse, mutect2
- PIGO | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99956377; called by muse, mutect2
- PLPP4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1350031130, COSV64826815; called by muse, mutect2
- RNF213 | c.13522G>A p.G4508S | Missense Mutation (SNP) | VAF 54/808 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765019511, COSV100299566; called by muse, mutect2
- RPS6KA6 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV99424017; called by muse, mutect2, varscan2
- SLC6A2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 19/586 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54913583; called by muse, mutect2
- ACMSD | c.309C>T p.T103= | Silent (SNP) | VAF 41/478 reads (9%) | catalogued as rs946527173; called by muse, mutect2
- ATRX | c.1938A>G p.L646= | Silent (SNP) | VAF 52/933 reads (6%) | catalogued as COSV100969931; called by muse, mutect2
- F7 | c.861G>A p.Q287= | Silent (SNP) | VAF 28/331 reads (8%) | catalogued as COSV100660933; called by muse, mutect2
- FER1L6 | c.2718C>T p.D906= | Silent (SNP) | VAF 39/600 reads (7%) | catalogued as rs532200482, COSV101205377; called by muse, mutect2
- IL10RB | c.216G>A p.T72= | Silent (SNP) | VAF 16/516 reads (3%) | catalogued as rs1288950257; called by muse, mutect2
- MUC16 | c.31170G>A p.R10390= | Silent (SNP) | VAF 29/775 reads (4%) | catalogued as COSV101197858; called by muse, mutect2
- MXRA5 | c.4689C>T p.S1563= | Silent (SNP) | VAF 28/541 reads (5%) | catalogued as COSV54231541; called by muse, mutect2
- PLEKHM2 | c.316T>C p.L106= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs1015462025; called by muse, varscan2
- STARD7 | c.273G>A p.Q91= | Silent (SNP) | VAF 16/227 reads (7%) | catalogued as COSV100474442; called by muse, mutect2
- TRO | c.3813C>T p.G1271= | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as rs368748764, COSV99435974; called by muse, mutect2, varscan2
- ZNF526 | c.1569G>A p.T523= | Silent (SNP) | VAF 27/273 reads (10%) | called by muse, mutect2
